MMRF case MMRF_1727 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/770685f0-96ae-4f29-a748-e6593e10b931

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.9 years (26,264 days); ISS stage: III; Days to last known disease status: 1,156 days (3.2 years); Days to last follow up: 1,156 days (3.2 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 372 days (1.0 years).
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 344 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 9 days; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 831 days (2.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 2): M Protein 4.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.625 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 52.6 g/L; Immunoglobulin A 0.074 g/L; Immunoglobulin M 0.131 g/L; Beta 2 Microglobulin 6.84 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 4.11 ×10⁹/L; Absolute Neutrophil 1.95 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 1.88 mmol/L; Albumin 28.1 g/L; Total Protein 8.7 g/dL; Glucose 5.45 mmol/L; C-Reactive Protein 1.58 mg/dL.
- Day 83 (ECOG 1): M Protein 1.39 g/dL; Immunoglobulin G 19.2 g/L; Immunoglobulin A 0.103 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 7.13 ×10⁹/L; Absolute Neutrophil 4.08 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 70.7 µmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 7.37 mmol/L.
- Day 169 (ECOG 1): M Protein 0.85 g/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.117 g/L; Immunoglobulin M 0.321 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 7.41 ×10⁹/L; Absolute Neutrophil 4.59 ×10⁹/L; Platelets 288 ×10⁹/L; Creatinine 73.4 µmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 7.04 mmol/L.
- Day 260 (ECOG 1): M Protein 0.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0672 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.0369 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 0.316 g/L; Immunoglobulin M 0.317 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 7.22 ×10⁹/L; Absolute Neutrophil 4.29 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 95.5 µmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 6.93 mmol/L.
- Day 344 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.713 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.251 g/L; Immunoglobulin M 0.416 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.69 ×10⁹/L; Absolute Neutrophil 3.38 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 91.9 µmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 7.4 g/dL; Glucose 6.82 mmol/L.
- Day 442 (ECOG 1): M Protein 0.73 g/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.59 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 9.73 mmol/L; Leukocytes 6.58 ×10⁹/L; Absolute Neutrophil 4.03 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 84.9 µmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 7.4 g/dL; Glucose 6.11 mmol/L.
- Day 526 (ECOG 1): M Protein 0.83 g/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 0.541 g/L; Immunoglobulin M 0.454 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 9.73 mmol/L; Leukocytes 7.07 ×10⁹/L; Absolute Neutrophil 4.44 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 87.5 µmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 5.89 mmol/L.
- Day 610 (ECOG 1): M Protein 1.27 g/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 0.626 g/L; Immunoglobulin M 0.468 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 10.4 mmol/L; Leukocytes 7.44 ×10⁹/L; Absolute Neutrophil 4.69 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 99 µmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 7.81 mmol/L.
- Day 715 (ECOG 1): M Protein 2.27 g/dL; Immunoglobulin G 29.5 g/L; Immunoglobulin A 0.506 g/L; Immunoglobulin M 0.421 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 9.92 mmol/L; Leukocytes 8.31 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 89.3 µmol/L; Calcium 2.39 mmol/L; Albumin 43.1 g/L; Total Protein 8.7 g/dL; Glucose 6.27 mmol/L.
- Day 771 (ECOG 1): M Protein 2.96 g/dL; Immunoglobulin G 37 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 9.67 mmol/L; Leukocytes 6.84 ×10⁹/L; Absolute Neutrophil 3.83 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 94.6 µmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 8.9 g/dL; Glucose 7.26 mmol/L.
- Day 883 (ECOG 1): M Protein 5.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.09 mg/dL; Immunoglobulin G 62.4 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 6.68 ×10⁹/L; Absolute Neutrophil 4.15 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 84 µmol/L; Calcium 2.23 mmol/L; Albumin 40.9 g/L; Total Protein 11.2 g/dL; Glucose 7.81 mmol/L.
- Day 967 (ECOG 1): M Protein 2.12 g/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.02 ×10⁹/L; Absolute Neutrophil 2.62 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 86.6 µmol/L; Calcium 2.1 mmol/L; Albumin 34.4 g/L; Total Protein 7.5 g/dL; Glucose 6.38 mmol/L.
- Day 1,058 (ECOG 1): M Protein 1.76 g/dL; Immunoglobulin G 24 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 5.08 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 87.5 µmol/L; Calcium 2.2 mmol/L; Albumin 38.2 g/L; Total Protein 7.6 g/dL; Glucose 9.57 mmol/L.
- Day 1,156 (ECOG 1): M Protein 1.19 g/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.41 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 83.1 µmol/L; Calcium 2.15 mmol/L; Albumin 35.2 g/L; Total Protein 6.6 g/dL; Glucose 5.56 mmol/L.

Other clinical attributes
- Day -13: Weight: 66 kg; Height: 166 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1727_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1727_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
